Gene-level copy-number profile of tumor specimen TCGA-CH-5772-01A from TCGA case TCGA-CH-5772, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,194 days).
Specimen TCGA-CH-5772-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ec9c1dc1-ecb8-4e90-b401-9b4618a05b5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5772-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/393332fc-ff38-4d55-8230-e7338916c0af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 5,132; copy number 2: 54,652.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5772-01A-11D-1574-01): tumor purity 0.8, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,019,340–177,228,000, 1 gene (within-gene range 0–2): TBL1XR1.
- chr3:177,120,691–177,767,379, 11 genes (within-gene range 0–1): Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4.
- chr10:114,294,824–116,477,957, 22 genes (within-gene range 0–2): AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1, NTAN1P1, GFRA1, AC012470.1, CCDC172, SNRPGP6, PNLIPRP3, HMGB3P8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
